Somatic mutation profile of tumor specimen ALCH-B2S6-TTP1-A (aliquot ALCH-B2S6-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2S6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Pleomorphic carcinoma; Age at diagnosis: 68.9 years (25,149 days).
Specimen ALCH-B2S6-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0e23171-3dcc-4acd-b546-d08b2202b3f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2S6-NB1-A (Blood Derived Normal), aliquot ALCH-B2S6-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb2d5a49-1cfb-4d72-93aa-0581cec3593d

The open-access MAF lists 188 somatic variants for this specimen: 133 protein-altering or splice-affecting, 31 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 31, Intron 14, Nonsense Mutation 6, Frame Shift Del 5, 3'UTR 4, RNA 4, Splice Region 2, 5'Flank 2, Splice Site 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 235/364 reads (65%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1216-1G>T p.X406_splice | Splice Site (SNP) | VAF 95/143 reads (66%) | hotspot (GDC flag); catalogued as CS971888, COSV57295479, COSV57298451, COSV57332521; called by muse, mutect2, varscan2
- ABCB1 | c.421G>T p.G141* | Nonsense Mutation (SNP) | VAF 141/456 reads (31%) | catalogued as COSV55950374; called by muse, mutect2, varscan2
- ANGPTL4 | c.1089C>G p.Y363* | Nonsense Mutation (SNP) | VAF 79/243 reads (33%) | catalogued as rs369070552, CM164631; called by muse, mutect2, varscan2
- ANKS1A | c.2305G>A p.G769R | Missense Mutation (SNP) | VAF 94/245 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370130506; called by muse, mutect2, varscan2
- ATP10A | c.4125G>T p.M1375I | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV63526538; called by muse, mutect2, varscan2
- CCSAP | c.151del p.D51Tfs*35 | Frame Shift Del (DEL) | VAF 45/120 reads (38%) | catalogued as COSV52909554; called by mutect2, pindel, varscan2
- COL22A1 | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 87/168 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); catalogued as rs1192688002, COSV57341410, COSV99079048; called by muse, mutect2, varscan2
- COLGALT1 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761435653, COSV53109654; called by muse, mutect2, varscan2
- CPNE1 | c.989A>G p.Y330C (on ENST00000352393; = p.Y335C on NM_003915.5) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757799480; called by muse, mutect2, varscan2
- DMTN | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs1339253996; called by muse, mutect2, varscan2
- DNAH8 | c.6568A>G p.T2190A | Missense Mutation (SNP) | VAF 76/187 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); catalogued as COSV100544467; called by muse, mutect2, varscan2
- ELFN1 | c.2109C>A p.H703Q | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs1255619860; called by muse, mutect2, varscan2
- FAM71B | c.1124C>A p.A375E | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.096); catalogued as COSV57227450; called by muse, mutect2, varscan2
- FBN3 | c.6295G>C p.V2099L | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV54464251, COSV99561273; called by muse, mutect2, varscan2
- GALR3 | c.587C>A p.P196H | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348511192; called by muse, mutect2, varscan2
- GCNA | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 42/530 reads (8%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs753093676, COSV65467356; called by muse, mutect2
- GUCY2F | c.3218C>A p.P1073H | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54306358; called by muse, mutect2, varscan2
- HPN | c.414-3C>T | Splice Region (SNP) | VAF 113/364 reads (31%) | catalogued as rs1233561771; called by muse, mutect2, varscan2
- HS6ST3 | c.805C>T p.H269Y | Missense Mutation (SNP) | VAF 58/91 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65002191; called by muse, mutect2, varscan2
- KCNH6 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 150/210 reads (71%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs778276731, COSV59002595; called by muse, mutect2, varscan2
- KDM5C | c.3548C>G p.S1183C | Missense Mutation (SNP) | VAF 145/306 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.682); catalogued as COSV64763303; called by muse, mutect2, varscan2
- MAGEA12 | c.156G>T p.E52D | Missense Mutation (SNP) | VAF 116/358 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.204); catalogued as COSV63294545; called by muse, mutect2, varscan2
- MAGEB4 | c.289G>C p.A97P | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs772416089; called by muse, mutect2, varscan2
- MAGEL2 | c.1784C>A p.P595Q | Missense Mutation (SNP) | VAF 84/190 reads (44%) | SIFT tolerated, low confidence (0.11); catalogued as COSV100045897; called by muse, mutect2, varscan2
- MC3R | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 204/636 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1286756644, COSV54762849; called by muse, mutect2, varscan2
- MC5R | c.398T>G p.L133* | Nonsense Mutation (SNP) | VAF 16/376 reads (4%) | catalogued as rs1383233816; called by muse, mutect2
- MED13L | c.3197C>T p.A1066V | Missense Mutation (SNP) | VAF 68/88 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV56130109; called by muse, mutect2, varscan2
- NALCN | c.1427A>T p.Y476F | Missense Mutation (SNP) | VAF 76/89 reads (85%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV99214081; called by muse, mutect2, varscan2
- NBEA | c.7562del p.L2521* | Frame Shift Del (DEL) | VAF 86/165 reads (52%) | catalogued as COSV59807588; called by mutect2, pindel, varscan2
- NCAM2 | c.806G>T p.R269M | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.898); catalogued as rs1459403311; called by muse, mutect2, varscan2
- OPRL1 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 158/313 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100402283; called by muse, mutect2, varscan2
- OR1L8 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.721); catalogued as COSV100508366; called by muse, mutect2, varscan2
- OXR1 | c.1369A>G p.N457D (on ENST00000442977 / NM_001198532.1; = p.N456D on NM_018002.3) | Missense Mutation (SNP) | VAF 129/261 reads (49%) | SIFT tolerated (0.6); PolyPhen benign (0.055); catalogued as COSV56333186; called by muse, mutect2, varscan2
- PLB1 | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 105/307 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs778756062, COSV59819943; called by muse, mutect2, varscan2
- PLCXD3 | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 98/217 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV60612432; called by muse, mutect2, varscan2
- POM121L12 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 10/231 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.072); catalogued as COSV68692610; called by muse, mutect2
- PPP1R12C | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.986); catalogued as rs898692203; called by muse, mutect2
- QSOX1 | c.1540A>G p.N514D | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1424597642; called by muse, mutect2, varscan2
- RASAL3 | c.2900G>T p.R967L | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV54607187; called by muse, mutect2, varscan2
- RBMXL2 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 348/528 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs775110175, COSV60982312; called by muse, mutect2, varscan2
- SDK1 | c.1394G>A p.G465E | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1282983487, COSV101269764; called by muse, mutect2
- SHROOM4 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs782477463; called by muse, mutect2, varscan2
- SLC5A5 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 129/320 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.161); catalogued as rs369704282; called by muse, mutect2, varscan2
- SPANXN2 | c.14C>A p.T5N | Missense Mutation (SNP) | VAF 101/279 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs782426346; called by muse, mutect2, varscan2
- SUFU | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 68/89 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1443773793, COSV64014677; called by muse, mutect2, varscan2
- TGIF2LX | c.203G>T p.W68L | Missense Mutation (SNP) | VAF 131/361 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99383266; called by muse, mutect2, varscan2
- TMEM121B | c.1615T>C p.S539P | Missense Mutation (SNP) | VAF 86/287 reads (30%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs756859251; called by muse, mutect2, varscan2
- USH2A | c.8755A>G p.T2919A | Missense Mutation (SNP) | VAF 113/292 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as CM149623; called by muse, mutect2, varscan2
- USP17L7 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 242/1344 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs1285863080; called by muse, varscan2
- VWDE | c.4547G>C p.R1516P | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV51724572; called by muse, mutect2
- WAC | c.446A>G p.N149S | Missense Mutation (SNP) | VAF 87/134 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763061014, COSV61568037; called by muse, mutect2, varscan2
- ZC2HC1A | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as rs777639391; called by muse, mutect2, varscan2
- ZNF843 | c.121G>T p.G41C | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV59848282; called by muse, mutect2, varscan2
- ZSCAN30 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 32/372 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs373204256; called by muse, mutect2
- A4GNT | c.749T>C p.L250P | Missense Mutation (SNP) | VAF 205/428 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ABCB1 | c.2497C>A p.L833I | Missense Mutation (SNP) | VAF 119/346 reads (34%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS19 | c.3586C>T p.R1196C | Missense Mutation (SNP) | VAF 94/200 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRB3 | c.280del p.S94Pfs*5 | Frame Shift Del (DEL) | VAF 106/304 reads (35%) | called by mutect2, varscan2
- ALG14 | c.431A>G p.N144S | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGEF5 | c.532_550del p.G178Lfs*63 | Frame Shift Del (DEL) | VAF 76/439 reads (17%) | called by mutect2, varscan2
- BAHCC1 | c.4685G>C p.S1562T | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2
- C1GALT1C1 | c.618G>C p.K206N | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CALD1 | c.671T>G p.V224G | Missense Mutation (SNP) | VAF 147/317 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCNB3 | c.2128T>A p.L710M | Missense Mutation (SNP) | VAF 12/221 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.168); called by muse, mutect2
- CFAP47 | c.4223C>G p.S1408* | Nonsense Mutation (SNP) | VAF 27/111 reads (24%) | called by muse, mutect2, varscan2
- CHP1 | c.431G>C p.G144A | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- CIT | c.2199G>C p.K733N | Missense Mutation (SNP) | VAF 95/163 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- COL4A3 | c.4019G>T p.G1340V | Missense Mutation (SNP) | VAF 335/433 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A5 | c.4036C>G p.H1346D | Missense Mutation (SNP) | VAF 87/171 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTNNA2 | c.2503C>A p.Q835K | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- CUX1 | c.356G>C p.R119T (on ENST00000292535 / NM_181552.4; = p.R130T on NM_001913.5) | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DMD | c.3574G>A p.E1192K | Missense Mutation (SNP) | VAF 108/269 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAH9 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DPF3 | c.637C>T p.L213F | Missense Mutation (SNP) | VAF 116/191 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- EIF2AK4 | c.2123C>T p.S708L | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- ENAM | c.435T>A p.N145K | Missense Mutation (SNP) | VAF 119/176 reads (68%) | SIFT tolerated (0.79); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FANCB | c.1637G>A p.G546E | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- FBL | c.62G>T p.R21L | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- FBN2 | c.5919C>G p.D1973E | Missense Mutation (SNP) | VAF 242/456 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- FRG2C | c.235G>T p.G79W | Missense Mutation (SNP) | VAF 42/731 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); called by muse, mutect2
- GBP1 | c.687C>G p.F229L | Missense Mutation (SNP) | VAF 71/143 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- GHRHR | c.476G>A p.C159Y | Missense Mutation (SNP) | VAF 202/474 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLT6D1 | c.112C>T p.H38Y | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- GNL3L | c.1573G>T p.V525L | Missense Mutation (SNP) | VAF 113/348 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR158 | c.2510A>T p.E837V | Missense Mutation (SNP) | VAF 143/201 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- HECW1 | c.674C>A p.P225Q | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INTS12 | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 84/150 reads (56%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IRF2BP1 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ITGA9 | c.346T>G p.C116G | Missense Mutation (SNP) | VAF 60/75 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- KCNH6 | c.1286A>T p.Y429F | Missense Mutation (SNP) | VAF 81/117 reads (69%) | SIFT tolerated (0.26); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- KCNK5 | c.182T>A p.L61Q | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- KNTC1 | c.3216G>T p.L1072F | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- LRRC7 | c.2114C>A p.T705N (on ENST00000651989 / NM_001370785.2; = p.T672N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- LYST | c.11294A>G p.H3765R | Missense Mutation (SNP) | VAF 131/395 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MAPK12 | c.325A>T p.M109L | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- MEGF10 | c.263A>G p.Y88C | Missense Mutation (SNP) | VAF 47/216 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MUC16 | c.37520A>G p.H12507R | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- MYBL1 | c.29A>C p.E10A | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- MYO5B | c.5527G>A p.E1843K | Missense Mutation (SNP) | VAF 145/459 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- NALCN | c.1428C>A p.Y476* | Nonsense Mutation (SNP) | VAF 77/90 reads (86%) | called by muse, mutect2, varscan2
- NAV3 | c.1171G>T p.V391F | Missense Mutation (SNP) | VAF 131/224 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- OR10T2 | c.536T>C p.F179S | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PAPPA2 | c.717C>A p.S239R | Missense Mutation (SNP) | VAF 91/354 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH8 | c.2063C>A p.A688E | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- PCDHA12 | c.2212A>T p.T738S | Missense Mutation (SNP) | VAF 241/446 reads (54%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PEA15 | c.266T>A p.I89N | Missense Mutation (SNP) | VAF 175/385 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PGM2 | c.608G>T p.W203L | Missense Mutation (SNP) | VAF 70/90 reads (78%) | SIFT tolerated (0.22); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PLPPR3 | c.938C>A p.S313* (on ENST00000520876 / NM_001270366.2; = p.S341* on NM_024888.2) | Nonsense Mutation (SNP) | VAF 26/92 reads (28%) | called by muse, mutect2, varscan2
- POM121L12 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.06); called by muse, mutect2
- POSTN | c.1727G>C p.G576A | Missense Mutation (SNP) | VAF 128/196 reads (65%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRAMEF12 | c.464A>G p.N155S | Missense Mutation (SNP) | VAF 150/315 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2
- PRDM5 | c.1634A>G p.Y545C | Missense Mutation (SNP) | VAF 238/317 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PREX2 | c.2432C>G p.T811R | Missense Mutation (SNP) | VAF 68/306 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PTPN21 | c.2047C>A p.Q683K | Missense Mutation (SNP) | VAF 93/144 reads (65%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRO | c.3229G>A p.A1077T (on ENST00000281171 / NM_030667.3; = p.A1049T on NM_002848.4) | Missense Mutation (SNP) | VAF 227/316 reads (72%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RAB28 | c.505T>C p.C169R | Missense Mutation (SNP) | VAF 76/110 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- RAB3GAP2 | c.4027-3C>T | Splice Region (SNP) | VAF 25/346 reads (7%) | called by muse, mutect2
- RASGEF1C | c.1052G>C p.R351P | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEC16A | c.6265_6268del p.K2089Dfs*52 | Frame Shift Del (DEL) | VAF 106/300 reads (35%) | called by mutect2, pindel, varscan2
- SLC35E1 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLITRK3 | c.2351C>T p.P784L | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRCAP | c.7843A>C p.S2615R | Missense Mutation (SNP) | VAF 94/206 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- STAT5B | c.1214A>G p.Y405C | Missense Mutation (SNP) | VAF 201/269 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- SYCP1 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TP53 | c.370_375+12del p.X124_splice | Splice Site (DEL) | VAF 14/34 reads (41%) | called by mutect2, pindel, varscan2
- TRAV17 | c.68A>G p.Q23R | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated (0.09); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- TRMT1L | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TUT7 | c.1132A>G p.N378D | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.734); called by muse, mutect2
- VPS13D | c.13081A>G p.I4361V | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- ZFAT | c.754A>T p.T252S | Missense Mutation (SNP) | VAF 122/299 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- ZGPAT | c.657G>T p.Q219H | Missense Mutation (SNP) | VAF 68/245 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF534 | c.1277A>T p.N426I (on ENST00000332323 / NM_001143939.3; = p.N413I on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ABCB10 | c.870C>G p.L290= | Silent (SNP) | VAF 140/322 reads (43%) | catalogued as rs1333835906; called by muse, mutect2, varscan2
- BSPRY | c.745C>A p.R249= | Silent (SNP) | VAF 58/131 reads (44%) | called by muse, mutect2, varscan2
- CD93 | c.810C>T p.G270= | Silent (SNP) | VAF 13/277 reads (5%) | called by muse, mutect2
- CSMD2 | c.2028G>A p.K676= | Silent (SNP) | VAF 29/53 reads (55%) | catalogued as COSV53912186; called by muse, mutect2
- CTNNA2 | c.2142G>T p.L714= | Silent (SNP) | VAF 86/197 reads (44%) | called by muse, mutect2, varscan2
- DEPDC1 | c.1236A>G p.L412= | Silent (SNP) | VAF 79/285 reads (28%) | catalogued as rs771080626; called by muse, mutect2, varscan2
- DLGAP4 | c.1173C>G p.T391= | Silent (SNP) | VAF 25/199 reads (13%) | catalogued as rs746120286, COSV59420266; called by muse, varscan2
- DPPA4 | c.726A>T p.T242= | Silent (SNP) | VAF 118/248 reads (48%) | called by muse, mutect2, varscan2
- EFCC1 | c.1302G>A p.A434= | Silent (SNP) | VAF 87/231 reads (38%) | catalogued as rs370363130; called by muse, mutect2, varscan2
- EVPL | c.3180A>G p.L1060= | Silent (SNP) | VAF 72/119 reads (61%) | catalogued as rs1444334660; called by muse, mutect2, varscan2
- FETUB | c.285G>T p.V95= | Silent (SNP) | VAF 126/519 reads (24%) | called by muse, mutect2, varscan2
- GFRAL | c.192A>G p.S64= | Silent (SNP) | VAF 40/103 reads (39%) | called by muse, mutect2, varscan2
- GPER1 | c.111C>G p.L37= | Silent (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- IARS1 | c.528G>A p.V176= | Silent (SNP) | VAF 24/92 reads (26%) | called by muse, mutect2, varscan2
- INPP5D | c.330C>T p.D110= | Silent (SNP) | VAF 78/105 reads (74%) | catalogued as rs780515179, COSV64037618; called by muse, mutect2, varscan2
- KCNK5 | c.183A>T p.L61= | Silent (SNP) | VAF 60/156 reads (38%) | called by muse, mutect2
- KCNV1 | c.639C>T p.G213= | Silent (SNP) | VAF 93/341 reads (27%) | catalogued as rs374133519, COSV99819497; called by muse, mutect2, varscan2
- KRTAP19-5 | c.120C>A p.G40= | Silent (SNP) | VAF 263/617 reads (43%) | catalogued as COSV61858723, COSV61858900; called by muse, mutect2, varscan2
- MYBPH | c.1378C>T p.L460= | Silent (SNP) | VAF 117/235 reads (50%) | called by muse, mutect2, varscan2
- NEB | c.5601C>G p.T1867= | Silent (SNP) | VAF 144/374 reads (39%) | called by muse, mutect2, varscan2
- NHS | c.4101C>A p.A1367= | Silent (SNP) | VAF 72/195 reads (37%) | called by muse, mutect2, varscan2
- NR1I2 | c.864C>T p.F288= | Silent (SNP) | VAF 228/746 reads (31%) | called by muse, mutect2, varscan2
- PGK2 | c.825G>A p.K275= | Silent (SNP) | VAF 114/305 reads (37%) | catalogued as COSV59162756, COSV59165503; called by muse, mutect2, varscan2
- PNPLA3 | c.1188A>C p.R396= | Silent (SNP) | VAF 43/169 reads (25%) | catalogued as rs757911874; called by muse, mutect2, varscan2
- PSPH | c.348A>G p.V116= | Silent (SNP) | VAF 93/219 reads (42%) | called by muse, mutect2, varscan2
- RAB4A | c.618G>A p.R206= | Silent (SNP) | VAF 100/306 reads (33%) | called by muse, mutect2, varscan2
- SDK1 | c.3987C>T p.I1329= | Silent (SNP) | VAF 193/501 reads (39%) | catalogued as rs753458390, COSV67363192; called by muse, mutect2, varscan2
- SPTA1 | c.4185G>T p.L1395= | Silent (SNP) | VAF 238/560 reads (43%) | called by muse, mutect2, varscan2
- THPO | c.1386C>G p.P462= (on ENST00000649095 / NM_001290003.1; = p.P322= on NM_000460.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as rs1472659725; called by muse, mutect2, varscan2
- TRDN | c.891A>G p.E297= | Silent (SNP) | VAF 211/501 reads (42%) | called by muse, mutect2, varscan2
- ZNF536 | c.3498C>T p.S1166= | Silent (SNP) | VAF 120/356 reads (34%) | called by muse, mutect2, varscan2
- AC235097.1 | n.178T>G | RNA (SNP) | VAF 75/220 reads (34%) | called by muse, mutect2, varscan2
- ADCYAP1 | chr18:904832 C>T | 5'Flank (SNP) | VAF 113/238 reads (47%) | catalogued as rs1199153986; called by muse, mutect2, varscan2
- AP1S3 | c.*38_*43del | 3'UTR (DEL) | VAF 3/27 reads (11%) | catalogued as rs1559269620; called by pindel, varscan2*
- AQP10 | c.707+69C>T | Intron (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- BCORL1 | c.4306-2882C>G | Intron (SNP) | VAF 54/184 reads (29%) | catalogued as COSV54390206; called by muse, mutect2
- DCHS2 | n.6954T>C | RNA (SNP) | VAF 124/166 reads (75%) | called by muse, mutect2, varscan2
- DSC3 | c.*40G>T | 3'UTR (SNP) | VAF 53/119 reads (45%) | called by muse, mutect2, varscan2
- ELF2 | c.239-10629A>G | Intron (SNP) | VAF 135/202 reads (67%) | catalogued as rs1364946451; called by muse, mutect2, varscan2
- ERCC3 | c.472-13T>C | Intron (SNP) | VAF 298/368 reads (81%) | catalogued as rs759803173; called by muse, mutect2, varscan2
- EYS | c.1767-7665C>G | Intron (SNP) | VAF 8/17 reads (47%) | called by mutect2, varscan2
- GPC2 | c.729+86C>T | Intron (SNP) | VAF 81/243 reads (33%) | called by muse, mutect2, varscan2
- JAKMIP2 | c.*6C>T | 3'UTR (SNP) | VAF 147/325 reads (45%) | catalogued as rs1392584797; called by muse, mutect2, varscan2
- KRT87P | n.894C>A | RNA (SNP) | VAF 195/274 reads (71%) | called by muse, mutect2, varscan2
- LINC02381 | n.326C>A | RNA (SNP) | VAF 51/73 reads (70%) | called by muse, mutect2, varscan2
- MAP2K7 | c.124+1790A>G | Intron (SNP) | VAF 52/155 reads (34%) | called by muse, mutect2, varscan2
- MED12L | c.1969-903G>T | Intron (SNP) | VAF 215/429 reads (50%) | called by muse, mutect2, varscan2
- MFRP | chr11:119346351 G>T | 5'Flank (SNP) | VAF 351/485 reads (72%) | catalogued as COSV64128637; called by muse, mutect2, varscan2
- RAB40C | c.142+5899G>T | Intron (SNP) | VAF 58/123 reads (47%) | called by muse, mutect2, varscan2
- SELENOS | c.319-32A>G | Intron (SNP) | VAF 29/106 reads (27%) | called by muse, mutect2
- SLC4A11 | c.1463+24C>A | Intron (SNP) | VAF 74/284 reads (26%) | called by muse, mutect2, varscan2
- SLC5A5 | c.*29C>A | 3'UTR (SNP) | VAF 32/111 reads (29%) | called by muse, mutect2, varscan2
- STAG2 | c.3468-41G>A | Intron (SNP) | VAF 90/184 reads (49%) | called by muse, mutect2, varscan2
- SYNE1 | c.9972+110C>A | Intron (SNP) | VAF 149/392 reads (38%) | called by muse, mutect2, varscan2
- TMEM222 | c.279+211G>T | Intron (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2
